CGCI case HTMCP-02-01-01248 — HIV+ Tumor Molecular Characterization Project - Lung Cancer (CGCI-HTMCP-LC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/4f43937d-d529-4f14-932d-1977ea85eeca

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Vital status: Dead.

Diagnoses (1)
1. Primary of the upper lobe, lung (histology not recorded by GDC). ICD-O-3 morphology code: 8480/3; Site of resection or biopsy: Lung, NOS; Year of diagnosis: 2009; Method of diagnosis: Surgical Resection; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage I; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 0 days.
   Pathology details: Lymph nodes positive: 0; Lymph nodes tested: 9.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 0.

Molecular and laboratory tests
- NKX2-1 (IHC): Positive.
- Test (IHC): Negative; Specialized molecular test: P40.

Other clinical attributes
- Day 0: Risk factors: Hepatitis C Infection.
- Day 0: Comorbidities: Hepatitis C Infection.
- Day 0: Weight: 77.11 kg; Height: 177.8 cm; BMI: 24.4; CD4 count: 869; Haart treatment indicator: Yes; HIV viral load: 48.
- Comorbidities: HIV/AIDS.
- Risk factors: HIV/AIDS.

Exposures
- Tobacco smoking status: Current Smoker; Pack years smoked: 30.

Biospecimens (2 samples)
- Sample HTMCP-02-01-01248-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HTMCP-02-01-01248-01Z: Sample type: Tumor; Tissue type: Tumor.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Adenocarcinoma, mucinous, NOS; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Lost to follow-up: No; Tobacco smoking history indicator: 2; New tumor event diagnosis indicator: No.
- Anatomic neoplasm subdivision list: Anatomic organ subdivision: Upper lobe.
- History of disease: Year of HIV diagnosis: 1991; Haart therapy at diagnosis: Yes; Haart therapy prior to diagnosis: Yes; History relevant infectious diagnosis: Hepatitis C.
- Primary pathology: Lymph nodes examined: Yes.

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-LC_biospecimenSupplementSpreadsheet_20220304.xlsx, for sample HTMCP-02-01-01248-01A-01E-17519:
- % tumour top: 70
- % tumour bottom: 70

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-LC_biospecimenSupplementSpreadsheet_20220304.xlsx, for sample HTMCP-02-01-01248-01A-01S-17519:
- % tumour top: 70
- % tumour bottom: 70
